Somatic mutation profile of tumor specimen MP2PRT-PAVSRS-TBP1-A (aliquot MP2PRT-PAVSRS-TBP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAVSRS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.2 years (3,362 days).
Specimen MP2PRT-PAVSRS-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f7ddc25-7f14-490d-9da1-7069f92ff537.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVSRS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVSRS-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18a40c08-0642-4586-8a0f-484f709456a0

The open-access MAF lists 52 somatic variants for this specimen: 37 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 13, Frame Shift Ins 2, 5'Flank 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL592490.1 | c.759T>A p.H253Q | Missense Mutation (SNP) | VAF 106/382 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1447007612, COSV101308054; called by muse, mutect2, varscan2
- ALCAM | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 82/246 reads (33%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.985); catalogued as COSV60249026; called by muse, mutect2, varscan2
- AMDHD2 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 205/661 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1198917070; called by muse, mutect2, varscan2
- CDR2L | c.1241G>A p.G414E | Missense Mutation (SNP) | VAF 134/576 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.206); catalogued as COSV61501437; called by muse, mutect2
- CHST8 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 199/617 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs759507836; called by muse, mutect2, varscan2
- DSCAM | c.4880G>A p.R1627K | Missense Mutation (SNP) | VAF 116/536 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as COSV68029348; called by muse, mutect2, varscan2
- ERCC6L2 | c.1898C>T p.S633F | Missense Mutation (SNP) | VAF 48/209 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV56629277; called by muse, mutect2, varscan2
- EZH2 | c.2064T>A p.N688K (on ENST00000460911 / NM_001203247.2; = p.N693K on NM_004456.5) | Missense Mutation (SNP) | VAF 92/292 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57458670; called by muse, mutect2, varscan2
- FLT3 | c.2417C>T p.S806L | Missense Mutation (SNP) | VAF 72/219 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs769640419, COSV54068971; called by muse, mutect2, varscan2
- IQSEC3 | c.1045C>T p.R349W (on ENST00000538872 / NM_001170738.2; = p.R46W on NM_015232.1) | Missense Mutation (SNP) | VAF 19/660 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58286189; called by muse, mutect2
- ITIH5 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 59/335 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as COSV53673877; called by muse, mutect2, varscan2
- JAG2 | c.3673G>A p.A1225T | Missense Mutation (SNP) | VAF 107/578 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as rs140910378; called by muse, mutect2, varscan2
- KCNJ6 | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 106/564 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV55716433; called by muse, mutect2, varscan2
- LRIT1 | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 125/770 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as rs1301563560; called by muse, mutect2, varscan2
- MYMK | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 97/367 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as rs761023212, COSV101301185; called by muse, mutect2, varscan2
- POLR3A | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 60/432 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1334901941; called by muse, mutect2, varscan2
- RNASE11 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 65/293 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.025); catalogued as COSV60087724; called by muse, mutect2, varscan2
- RYR1 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 119/411 reads (29%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.459); catalogued as rs144845360; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERPINA12 | c.720G>A p.M240I | Missense Mutation (SNP) | VAF 125/530 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57942083; called by muse, mutect2, varscan2
- SLC6A5 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 207/697 reads (30%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs749736055; called by muse, mutect2, varscan2
- SV2C | c.496G>A p.G166S | Missense Mutation (SNP) | VAF 54/308 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as rs779809294, COSV59220164; called by muse, mutect2, varscan2
- TMEM150B | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 166/577 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs759105710, COSV58594106; called by muse, mutect2, varscan2
- TMEM273 | c.269G>A p.R90K | Missense Mutation (SNP) | VAF 101/609 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as rs768279430, COSV65154034; called by muse, mutect2, varscan2
- ZNF532 | c.3197C>T p.S1066L | Missense Mutation (SNP) | VAF 65/324 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as rs1010167151; called by muse, mutect2, varscan2
- AL592490.1 | c.760G>T p.G254C | Missense Mutation (SNP) | VAF 109/383 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ANK3 | c.10810C>T p.H3604Y | Missense Mutation (SNP) | VAF 106/657 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- ASB17 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 70/235 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- CREBBP | c.6079C>T p.P2027S | Missense Mutation (SNP) | VAF 182/586 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ECHDC2 | c.703G>A p.A235T (on ENST00000371522 / NM_001198961.2; = p.A204T on NM_018281.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/289 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXO15 | c.611A>G p.E204G | Missense Mutation (SNP) | VAF 29/279 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KMT2C | c.5214_5215insAACC p.P1739Nfs*11 | Frame Shift Ins (INS) | VAF 42/248 reads (17%) | called by mutect2, pindel, varscan2
- MMP2 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 127/480 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.071); called by muse, mutect2
- MOK | c.705G>A p.M235I | Missense Mutation (SNP) | VAF 74/273 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- RASA2 | c.1769C>T p.S590L | Missense Mutation (SNP) | VAF 74/209 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- RIMS1 | c.2050C>T p.Q684* | Nonsense Mutation (SNP) | VAF 50/258 reads (19%) | called by muse, mutect2, varscan2
- SENP6 | c.2739_2740insGCCT p.N914Afs*2 | Frame Shift Ins (INS) | VAF 42/296 reads (14%) | called by mutect2, pindel, varscan2
- STAT5B | c.1789T>C p.F597L | Missense Mutation (SNP) | VAF 53/222 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- AGAP1 | c.1761C>T p.I587= (on ENST00000304032 / NM_001037131.3; = p.I534= on NM_014914.5) | Silent (SNP) | VAF 55/380 reads (14%) | catalogued as rs1559213426, COSV58328684; called by muse, mutect2, varscan2
- AMTN | c.99G>A p.P33= | Silent (SNP) | VAF 61/331 reads (18%) | catalogued as rs777319072, COSV59488832; called by muse, mutect2, varscan2
- CTSG | c.420G>C p.T140= | Silent (SNP) | VAF 161/690 reads (23%) | catalogued as COSV53535120; called by muse, mutect2, varscan2
- ESRRG | c.432A>C p.S144= | Silent (SNP) | VAF 88/340 reads (26%) | called by muse, mutect2, varscan2
- GRIK2 | c.627G>A p.K209= | Silent (SNP) | VAF 75/355 reads (21%) | catalogued as COSV59758659; called by muse, mutect2, varscan2
- KCNMB2 | c.501G>A p.R167= | Silent (SNP) | VAF 98/341 reads (29%) | catalogued as COSV64201251; called by muse, mutect2, varscan2
- KRTAP20-2 | c.57C>T p.G19= | Silent (SNP) | VAF 126/611 reads (21%) | catalogued as rs1194592664, COSV58182517; called by muse, mutect2, varscan2
- MYO1B | c.2922C>T p.P974= (on ENST00000304164; = p.P916= on NM_012223.5) | Silent (SNP) | VAF 85/286 reads (30%) | called by muse, mutect2, varscan2
- NCAN | c.198G>A p.R66= | Silent (SNP) | VAF 148/467 reads (32%) | catalogued as rs1243111400; called by muse, mutect2, varscan2
- OR11H6 | c.992G>A p.*331= | Silent (SNP) | VAF 32/171 reads (19%) | catalogued as COSV100209789; called by muse, mutect2, varscan2
- PIWIL1 | c.165A>C p.T55= | Silent (SNP) | VAF 106/385 reads (28%) | called by muse, mutect2, varscan2
- PLG | c.1500G>A p.T500= | Silent (SNP) | VAF 88/443 reads (20%) | catalogued as rs775623839, COSV51981241; ClinVar: likely benign; called by muse, mutect2, varscan2
- TENM2 | c.1062G>A p.R354= (on ENST00000518659 / NM_001122679.2; = p.R163= on NM_001080428.3) | Silent (SNP) | VAF 99/362 reads (27%) | catalogued as rs1349088037, COSV69123747; called by muse, mutect2, varscan2
- DNAJB5 | c.-35+961G>A | Intron (SNP) | VAF 72/283 reads (25%) | called by muse, mutect2, varscan2
- FSIP2 | chr2:185738688 C>T | 5'Flank (SNP) | VAF 130/407 reads (32%) | called by muse, mutect2, varscan2
